Somatic mutation profile of tumor specimen TCGA-BG-A0MQ-01A (aliquot TCGA-BG-A0MQ-01A-11D-A10B-09) from TCGA case TCGA-BG-A0MQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 72.0 years (26,284 days).
Specimen TCGA-BG-A0MQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a32f55bf-00b4-4872-a5a8-0dac898b3ae2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0MQ-10A (Blood Derived Normal), aliquot TCGA-BG-A0MQ-10A-02D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e045502-819e-4590-81b0-ba0ab61c337f

The open-access MAF lists 752 somatic variants for this specimen: 581 protein-altering or splice-affecting, 161 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 383, Silent 161, Frame Shift Del 138, Frame Shift Ins 20, Nonsense Mutation 15, Splice Site 14, Intron 6, In Frame Del 6, Splice Region 4, 3'Flank 1, 5'Flank 1, 3'UTR 1.

Variants (750 of 752; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.6232C>T p.R2078* | Nonsense Mutation (SNP) | VAF 29/114 reads (25%) | catalogued as rs199422168, CM095684, COSV54125033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 35/84 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs121913478, CM960653, COSV60640350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 28/49 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 48/103 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 27/57 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 31/91 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADAT | c.388A>G p.N130D | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs1561020255, COSV61786840; called by muse, mutect2, varscan2
- ABCA7 | c.4422G>A p.W1474* | Nonsense Mutation (SNP) | VAF 22/193 reads (11%) | catalogued as COSV54024470; called by muse, mutect2, varscan2
- ABCC1 | c.829T>C p.Y277H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.247); catalogued as COSV60680723; called by muse, mutect2
- ABCC12 | c.2863G>A p.V955M | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.678); catalogued as rs200276015, COSV60911753; called by muse, mutect2, varscan2
- AC139530.2 | c.186dup p.K63Qfs*118 | Frame Shift Ins (INS) | VAF 64/182 reads (35%) | catalogued as rs769882870; called by mutect2, varscan2
- ACOX2 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57147760; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 62/122 reads (51%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADAM28 | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1173236719, COSV56097970; called by muse, varscan2
- ADAM7 | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV51535342; called by muse, mutect2, varscan2
- ADAMTS2 | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 128/281 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as rs200022037, COSV52365296; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY1 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs748614348, COSV52030450; called by muse, mutect2, varscan2
- ADCY6 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs370980658, COSV57166350; called by muse, mutect2, varscan2
- ADD2 | c.1084del p.E362Sfs*8 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | catalogued as COSV52471635; called by mutect2, pindel, varscan2
- ADGRB1 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1563692351, COSV60092172; called by muse, mutect2
- ADGRG4 | c.4712C>A p.A1571D | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54950063; called by muse, mutect2, varscan2
- AGBL1 | c.2130C>A p.Y710* | Nonsense Mutation (SNP) | VAF 50/100 reads (50%) | catalogued as COSV66849482; called by muse, mutect2, varscan2
- AGBL2 | c.2482del p.L828Wfs*8 | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | catalogued as rs1310675921; called by mutect2, pindel, varscan2
- AIFM1 | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0.017); catalogued as COSV54852653; called by muse, mutect2, varscan2
- AJM1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs758258222, COSV56031866; called by muse, mutect2, varscan2
- AKAP6 | c.6335A>G p.Y2112C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55205723; called by muse, mutect2, varscan2
- ALDH9A1 | c.1267A>G p.I423V | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61339068; called by muse, mutect2
- ALLC | c.394T>C p.W132R | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52993005, COSV52995013; called by muse, mutect2, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKRD11 | c.7736G>A p.R2579H | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1250432793, COSV56355400; called by muse, mutect2, varscan2
- ANKRD17 | c.7117T>C p.S2373P | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58215663; called by muse, mutect2, varscan2
- ANKRD35 | c.1184T>C p.V395A | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62909592; called by muse, mutect2
- ANKRD52 | c.3134C>T p.T1045M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs1352467677, COSV57282661; called by muse, mutect2, varscan2
- ANKRD53 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs141661790; called by muse, mutect2
- ANO7 | c.247G>A p.G83R (on ENST00000274979; = p.G29R on NM_001001666.4) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as rs543636867, COSV51468524; called by muse, mutect2, varscan2
- ARAP1 | c.2636C>T p.A879V (on ENST00000393609 / NM_001040118.2; = p.A634V on NM_015242.4) | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV61989478; called by muse, mutect2, varscan2
- ARFGEF3 | c.654A>T p.Q218H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV52450538; called by muse, mutect2, varscan2
- ARHGAP31 | c.3235A>G p.T1079A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV51789394; called by muse, mutect2, varscan2
- ARHGAP35 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68329291; called by muse, mutect2, varscan2
- ARSL | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV66964840; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 33/116 reads (28%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ARVCF | c.2204A>G p.N735S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs750193308, COSV52889115; called by muse, mutect2, varscan2
- ARVCF | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV54264875, COSV54266036; called by muse, mutect2, varscan2
- ASIC2 | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 106/238 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs201100877; called by muse, mutect2, varscan2
- ASTN2 | c.1591G>A p.G531R (on ENST00000313400 / NM_001365069.1; = p.G480R on NM_014010.5) | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776296190, COSV57752943, COSV57821120; called by muse, mutect2, varscan2
- ATAD5 | c.2716C>T p.L906F | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV58972183; called by muse, mutect2
- ATP11A | c.1966C>T p.L656F | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1220757657, COSV52106457; called by muse, mutect2, varscan2
- ATP11C | c.2336T>A p.L779Q | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV59559870; called by muse, mutect2, varscan2
- ATP13A2 | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs753825215, COSV58698309; called by muse, varscan2
- ATP13A2 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275277924, COSV58698317; called by muse, varscan2
- ATP2A3 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766349090, COSV59226290; called by muse, mutect2, varscan2
- ATP2C1 | c.2507T>A p.I836N | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV60752835; called by muse, mutect2, varscan2
- ATP7A | c.123A>C p.V41= | Splice Region (SNP) | VAF 26/69 reads (38%) | catalogued as COSV58442965; called by muse, mutect2, varscan2
- BAIAP2L1 | c.759del p.V254Cfs*10 | Frame Shift Del (DEL) | VAF 47/137 reads (34%) | catalogued as COSV99135180; called by mutect2, pindel, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BMT2 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as rs1020605621, COSV51774807; called by muse, mutect2, varscan2
- BPTF | c.643C>A p.R215S | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV58831824, COSV58844353, COSV58848236; called by muse, mutect2
- BRCA2 | c.8663G>A p.R2888H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs80359124, COSV66448556; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRPF1 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV57403324; called by muse, mutect2, varscan2
- C11orf65 | c.731+2T>C p.X244_splice | Splice Site (SNP) | VAF 73/175 reads (42%) | catalogued as COSV67596831; called by muse, mutect2, varscan2
- C16orf86 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as rs1478316381, COSV54675278; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 14/117 reads (12%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, pindel, varscan2
- C9orf72 | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.1); catalogued as rs139502204; called by muse, mutect2, varscan2
- CACNA1D | c.1747T>C p.F583L (on ENST00000350061 / NM_001128840.3; = p.F603L on NM_000720.4) | Missense Mutation (SNP) | VAF 27/293 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV55438179; called by muse, mutect2
- CACNA1E | c.3811C>T p.R1271C | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62383166; called by muse, mutect2, varscan2
- CACNA1I | c.2284G>A p.V762M | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370614164; called by muse, mutect2, varscan2
- CACNA2D3 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764584982, COSV55516465; called by muse, mutect2, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 144/290 reads (50%) | catalogued as rs1161545619; called by mutect2, pindel, varscan2
- CADPS | c.1214T>C p.M405T | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV51867874; called by muse, mutect2, varscan2
- CAGE1 | c.2081A>G p.Y694C (on ENST00000512086; = p.Y558C on NM_205864.3) | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV57074806; called by muse, mutect2, varscan2
- CALD1 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV62645254; called by muse, mutect2, varscan2
- CALML3 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as rs754327442, COSV59449136; called by muse, mutect2, varscan2
- CARD10 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs200768346, COSV52654467; called by muse, mutect2, varscan2
- CARD14 | c.1298G>T p.R433L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV60121940, COSV60127576; called by muse, mutect2, varscan2
- CARNMT1 | c.573T>A p.N191K | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV65190100; called by muse, mutect2, varscan2
- CASC3 | c.1460G>T p.R487L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.982); catalogued as COSV52866060; called by muse, mutect2, varscan2
- CCDC126 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs766969695, COSV56739185; called by muse, mutect2, varscan2
- CCDC141 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs755350129, COSV55368128; called by muse, mutect2, varscan2
- CCDC157 | c.2008T>A p.C670S | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV53175459; called by muse, mutect2, varscan2
- CCDC71L | c.190A>G p.M64V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV60070968; called by muse, mutect2, varscan2
- CCDC83 | c.914G>T p.R305I (on ENST00000342404 / NM_001286159.2; = p.R336I on NM_173556.5) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV54699902; called by muse, mutect2
- CCND1 | c.730C>A p.L244I | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV57119399; called by muse, mutect2, varscan2
- CCNG1 | c.330A>C p.E110D | Missense Mutation (SNP) | VAF 88/286 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV61651852; called by muse, mutect2, varscan2
- CDC7 | c.1268C>A p.A423D | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52309403; called by muse, mutect2, varscan2
- CDCP1 | c.1330C>T p.H444Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV56103787; called by muse, mutect2, varscan2
- CDH11 | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1481669427, COSV51751920; called by muse, mutect2, varscan2
- CDH17 | c.649G>T p.G217* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV50325866; called by muse, mutect2
- CDH23 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.185); catalogued as rs774061737, COSV54925193; called by muse, mutect2, varscan2
- CDH23 | c.6565C>T p.P2189S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.22); catalogued as rs368305683; called by muse, mutect2, varscan2
- CDK9 | c.627dup p.I210Hfs*2 | Frame Shift Ins (INS) | VAF 26/53 reads (49%) | catalogued as rs755440676; called by mutect2, varscan2
- CEP104 | c.2263A>G p.I755V | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs760664863, COSV65516252; called by muse, mutect2, varscan2
- CEP170B | c.3893G>A p.R1298Q (on ENST00000453495; = p.R1227Q on NM_015005.3) | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as rs368871311; called by muse, mutect2, varscan2
- CERS2 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54977778; called by muse, mutect2, varscan2
- CFAP53 | c.547del p.Q183Rfs*8 | Frame Shift Del (DEL) | VAF 113/303 reads (37%) | catalogued as COSV68351349; called by mutect2, pindel, varscan2
- CFAP70 | c.1840G>A p.V614I | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV60281123; called by muse, mutect2, varscan2
- CFAP97 | c.1193T>C p.L398P | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746018459, COSV57109250; called by muse, mutect2, varscan2
- CHD4 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 72/143 reads (50%) | catalogued as COSV58893592; called by muse, mutect2, varscan2
- CHIT1 | c.112del p.E38Rfs*24 | Frame Shift Del (DEL) | VAF 54/182 reads (30%) | catalogued as COSV55145321; called by mutect2, pindel, varscan2
- CHRM3 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776861962, COSV55080950; called by muse, mutect2, varscan2
- CHST1 | c.545T>C p.V182A | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV57321926; called by muse, mutect2
- CLDN23 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs373434191; called by mutect2, varscan2
- CLTC | c.3896T>C p.L1299P | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52245045; called by muse, mutect2, varscan2
- CNST | c.345A>T p.R115S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs1472500705, COSV63619834; called by muse, mutect2, varscan2
- CNTLN | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.127); catalogued as COSV52067119; called by muse, mutect2, varscan2
- COL4A6 | c.3059del p.P1020Lfs*12 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs775842525; called by mutect2, pindel, varscan2
- CPS1 | c.3398T>C p.V1133A | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1247417731, COSV51802712; called by muse, mutect2
- CRACD | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 56/402 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.758); catalogued as COSV51715500; called by muse, varscan2
- CREB3L4 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV55131431; called by muse, mutect2, varscan2
- CRLF1 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.412); catalogued as COSV66504166; called by muse, mutect2, varscan2
- CRNKL1 | c.2290_2292del p.E764del | In Frame Del (DEL) | VAF 56/196 reads (29%) | catalogued as rs757426818; called by pindel, varscan2
- CSF2RB | c.1701del p.S568Afs*130 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as rs757082963; called by mutect2, pindel, varscan2
- CSTF1 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53857951; called by muse, mutect2, varscan2
- CSTF2 | c.1302_1316del p.A452_E456del | In Frame Del (DEL) | VAF 22/72 reads (31%) | catalogued as rs779138581; called by mutect2, varscan2
- CTCF | c.935A>G p.H312R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50461922; called by muse, mutect2, varscan2
- CUEDC1 | c.152T>C p.M51T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1355801250, COSV64226060; called by muse, mutect2, varscan2
- CXCL5 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 103/246 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56018311; called by muse, mutect2, varscan2
- CXorf56 | c.443T>C p.I148T (on ENST00000536133 / NM_001170570.2; = p.I162T on NM_022101.4) | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV57437677; called by muse, mutect2, varscan2
- CYP4F22 | c.181del p.Q61Sfs*76 | Frame Shift Del (DEL) | VAF 29/77 reads (38%) | catalogued as CM060279; called by mutect2, pindel, varscan2
- DAPP1 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs1181646090, COSV56449862; called by muse, mutect2, varscan2
- DEFB127 | c.65A>G p.K22R | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.875); catalogued as COSV66688651; called by muse, mutect2, varscan2
- DENND2B | c.2938C>G p.Q980E | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV58201346; called by muse, mutect2, varscan2
- DENND2B | c.2456G>A p.R819H | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as rs200107974; called by muse, mutect2, varscan2
- DENND6A | c.1586T>A p.L529* | Nonsense Mutation (SNP) | VAF 115/270 reads (43%) | catalogued as COSV60767617; called by muse, mutect2, varscan2
- DGLUCY | c.779A>G p.K260R | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs779802230, COSV56364538; called by muse, mutect2, varscan2
- DHX30 | c.255+1G>A p.X85_splice (on ENST00000445061 / NM_138615.3; = p.X46_splice on NM_014966.3) | Splice Site (SNP) | VAF 71/169 reads (42%) | catalogued as COSV62393477; called by muse, mutect2, varscan2
- DIDO1 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.43); catalogued as rs150124990, COSV56614270; called by muse, mutect2, varscan2
- DIO1 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50776445; called by muse, mutect2, varscan2
- DNAH2 | c.9781C>T p.Q3261* | Nonsense Mutation (SNP) | VAF 56/130 reads (43%) | catalogued as COSV66716659; called by muse, mutect2, varscan2
- DNM1L | c.872+1G>C p.X291_splice | Splice Site (SNP) | VAF 10/58 reads (17%) | catalogued as COSV56772377; called by muse, mutect2, varscan2
- DNMT3A | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs752434188, COSV53039335; called by muse, mutect2, varscan2
- DNMT3B | c.1532G>A p.G511D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs200573841, COSV52415162; called by muse, mutect2, varscan2
- DPP7 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770087794, COSV65370975; called by muse, mutect2, varscan2
- DST | c.12173C>T p.A4058V (on ENST00000361203 / NM_001374722.1; = p.A1646V on NM_015548.5) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs1238268478, COSV54999072; called by muse, mutect2, varscan2
- DTNA | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as COSV51991551; called by muse, mutect2, varscan2
- DYNC1H1 | c.12638G>A p.R4213Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV100795328, COSV64134558; called by muse, mutect2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 31/77 reads (40%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EEF1A1 | c.1355C>A p.T452N | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV58548949; called by muse, mutect2, varscan2
- EFNB1 | c.464C>G p.T155R | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV52661035; called by muse, mutect2, varscan2
- EIF3I | c.112T>C p.Y38H | Missense Mutation (SNP) | VAF 181/489 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs1149056, COSV59083978; called by muse, mutect2, varscan2
- EIF4B | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50401656; called by muse, mutect2, varscan2
- EIF5A | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59747252; called by muse, mutect2
- ELOVL1 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360772987, COSV60521688; called by muse, mutect2, varscan2
- EP400 | c.6046A>G p.M2016V | Missense Mutation (SNP) | VAF 76/177 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV57763565; called by muse, mutect2, varscan2
- EPHB6 | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs145216040; called by muse, mutect2, varscan2
- ERCC1 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV50003718; called by muse, mutect2, varscan2
- ERCC6L2 | c.2084C>T p.T695M | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs761196717, COSV56628412; called by muse, mutect2, varscan2
- ERI1 | c.614A>G p.Q205R | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.208); catalogued as rs1239622887, COSV51570613; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 39/44 reads (89%) | catalogued as rs775950025; called by mutect2, varscan2
- FAM135B | c.3694C>T p.R1232W | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768874642, COSV52706786; called by muse, mutect2, varscan2
- FAM151B | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as COSV56471766; called by muse, mutect2, varscan2
- FAM71C | c.408del p.K136Nfs*5 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs762930877; called by mutect2, pindel, varscan2
- FAM83D | c.548G>A p.C183Y | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.343); catalogued as COSV54156597; called by muse, mutect2, varscan2
- FAT2 | c.9829G>A p.A3277T | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.326); catalogued as rs375652571; called by muse, mutect2, varscan2
- FAT4 | c.11129C>T p.T3710I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58672508; called by muse, mutect2, varscan2
- FBF1 | c.2202G>A p.T734= (on ENST00000586717; = p.T748= on NM_001319193.1) | Splice Region (SNP) | VAF 44/101 reads (44%) | catalogued as rs372392575; called by muse, mutect2, varscan2
- FBXO22 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 103/246 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1171779016, COSV57616708; called by muse, mutect2, varscan2
- FBXO31 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61147708; called by muse, mutect2, varscan2
- FCHO2 | c.840A>C p.E280D | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55106116; called by muse, mutect2, varscan2
- FLCN | c.773T>C p.F258S | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1435558928, COSV53257216; called by muse, mutect2, varscan2
- FN1 | c.5831C>T p.P1944L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV60547040; called by muse, mutect2, varscan2
- FNDC4 | c.30del p.S11Afs*17 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as rs771665646, COSV99253963; called by mutect2, varscan2
- FNTB | c.1047del p.L350Ffs*18 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | catalogued as rs768774237; called by mutect2, pindel, varscan2
- FOXE1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64300120; called by muse, mutect2, varscan2
- FRAS1 | c.2906T>A p.L969Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.133); catalogued as COSV53591264; called by muse, varscan2
- FRAS1 | c.2945T>G p.L982R | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53591288; called by muse, varscan2
- GABRB1 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 49/130 reads (38%) | catalogued as rs562056628, COSV54971426; called by muse, mutect2, varscan2
- GARRE1 | c.2579A>G p.Q860R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.979); catalogued as COSV55096764; called by muse, mutect2, varscan2
- GATAD2B | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV64083258; called by muse, mutect2, varscan2
- GDF2 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs201507315, CM1512095; called by muse, mutect2, varscan2
- GDF5 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.039); catalogued as rs147779125; called by muse, mutect2, varscan2
- GDPD1 | c.803T>C p.L268P | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52380729, COSV52384972; called by muse, mutect2, varscan2
- GIT2 | c.968A>G p.Y323C (on ENST00000355312 / NM_057169.5; = p.Y325C on NM_014776.5) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV58078291; called by muse, mutect2
- GJB7 | c.364T>C p.Y122H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV51528810; called by muse, mutect2, varscan2
- GLI1 | c.1318C>A p.P440T | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV57358240; called by muse, mutect2, varscan2
- GLI2 | c.4112C>T p.A1371V (on ENST00000361492 / NM_001374353.1; = p.A1388V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); catalogued as COSV58035079; called by muse, mutect2, varscan2
- GLIS3 | c.1841C>A p.P614H | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); catalogued as COSV60924293; called by muse, mutect2, varscan2
- GNAS | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.419); catalogued as COSV55671619; called by muse, mutect2, varscan2
- GNB3 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 130/326 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51831081; called by muse, mutect2, varscan2
- GPN1 | c.116T>G p.L39R | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV53112877; called by muse, mutect2, varscan2
- GPRIN3 | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV60884136, COSV60886453; called by muse, mutect2, varscan2
- GPSM2 | c.1766A>T p.D589V | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV51441126; called by muse, mutect2, varscan2
- GREB1 | c.933del p.K311Nfs*65 | Frame Shift Del (DEL) | VAF 86/227 reads (38%) | catalogued as rs869310688; called by mutect2, pindel, varscan2
- GRIA1 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs1380820240, COSV53589953; called by muse, mutect2, varscan2
- GRK2 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs746293222, COSV57950467; called by muse, mutect2
- GRM7 | c.2368A>T p.I790F | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63130629; called by muse, mutect2, varscan2
- GRM8 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.227); catalogued as rs13309334; called by muse, mutect2, varscan2
- GSE1 | c.1840C>A p.P614T | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV53669534; called by muse, varscan2
- HAPLN3 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV62084377; called by muse, mutect2, varscan2
- HECTD3 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV64669686; called by muse, mutect2, varscan2
- HECTD4 | c.5600A>G p.E1867G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV66386982; called by muse, mutect2, varscan2
- HELZ2 | c.6782G>A p.S2261N (on ENST00000467148 / NM_001037335.2; = p.S1692N on NM_033405.3) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV64442486; called by muse, mutect2, varscan2
- HGFAC | c.1300G>T p.G434W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66976616; called by muse, mutect2, varscan2
- HIPK4 | c.1851A>G p.*617Wext*2 | Nonstop Mutation (SNP) | VAF 52/112 reads (46%) | catalogued as rs1379893490, COSV52519304; called by muse, mutect2, varscan2
- HIVEP2 | c.3959C>T p.S1320L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs745789310, COSV50005753, COSV50099198; called by muse, mutect2, varscan2
- HMGCL | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs761552111, COSV52525153; called by muse, mutect2, varscan2
- HNF4A | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.089); catalogued as COSV57379988; called by muse, mutect2, varscan2
- IDS | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs1332401086, COSV61711266; called by muse, mutect2, varscan2
- IKBKE | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV65624362; called by muse, mutect2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | catalogued as rs776023104; called by mutect2, varscan2
- ILK | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 91/232 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs566678782, COSV54989672; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 12/17 reads (71%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- INTS13 | c.1467_1469del p.E489del | In Frame Del (DEL) | VAF 36/114 reads (32%) | catalogued as rs1334876338; called by pindel, varscan2
- IPCEF1 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs202118172, COSV54540811; called by muse, mutect2, varscan2
- ITIH2 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs139781584; called by muse, mutect2, varscan2
- ITPR3 | c.2189+1G>T p.X730_splice | Splice Site (SNP) | VAF 33/65 reads (51%) | catalogued as COSV65405966; called by muse, mutect2, varscan2
- KALRN | c.2656C>A p.L886I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53753766; called by muse, mutect2, varscan2
- KAT8 | c.812T>A p.L271Q | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54895218; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 42/109 reads (39%) | catalogued as rs1258313537; called by mutect2, pindel, varscan2
- KCNJ1 | c.923G>A p.C308Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60661294; called by muse, mutect2, varscan2
- KCNQ2 | c.2300G>A p.R767Q (on ENST00000359125 / NM_172107.4; = p.R739Q on NM_004518.6) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.019); catalogued as rs752551225, COSV60540405; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNS3 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); catalogued as rs745736584, COSV58405427; called by muse, mutect2, varscan2
- KIF1A | c.4203C>G p.H1401Q (on ENST00000320389 / NM_001379639.1; = p.H1393Q on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV57483155; called by muse, mutect2, varscan2
- KIF21B | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1356366486, COSV59752783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIRREL2 | c.1403T>C p.V468A | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as COSV52874470; called by muse, mutect2, varscan2
- KLF1 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV53434508, COSV53435613; called by muse, mutect2, varscan2
- KLF4 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.262); catalogued as rs767308895, COSV65928626, COSV65928830; called by muse, mutect2, varscan2
- KLK13 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as COSV50066844; called by muse, mutect2, varscan2
- KLK5 | c.21del p.W8Gfs*8 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as COSV60449953; called by mutect2, pindel, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2B | c.2806T>C p.S936P | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.172); catalogued as COSV55857421; called by muse, mutect2, varscan2
- KPNA3 | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 64/115 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV55503338; called by muse, mutect2, varscan2
- KRT16 | c.1076A>C p.N359T | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as COSV56967073; called by mutect2, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 47/98 reads (48%) | catalogued as rs770565486; called by mutect2, pindel, varscan2
- LAMC2 | c.2798G>A p.R933K | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as COSV51452633, COSV51454301; called by muse, mutect2, varscan2
- LARP6 | c.745C>A p.R249S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54579061; called by muse, mutect2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs746633076; called by mutect2, varscan2
- LCOR | c.1998G>T p.Q666H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV53714505; called by muse, mutect2
- LGALS9 | c.547G>A p.G183S (on ENST00000395473 / NM_009587.3; = p.G151S on NM_002308.4) | Missense Mutation (SNP) | VAF 171/736 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs746362908, COSV56348030; called by muse, mutect2, varscan2
- LGR4 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64863505; called by muse, mutect2, varscan2
- LHCGR | c.1436G>T p.R479L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV54292922, COSV54293675; called by muse, mutect2, varscan2
- LHX9 | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV61326843; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 101/228 reads (44%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LRFN2 | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1485565179, COSV57824137, COSV57831955; called by muse, mutect2, varscan2
- LRRC29 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.062); catalogued as COSV58526537; called by muse, mutect2, varscan2
- LRRC3 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs1425743029, COSV52398749; called by muse, varscan2
- LRRC31 | c.1624del p.R542Efs*37 | Frame Shift Del (DEL) | VAF 36/91 reads (40%) | catalogued as rs748577734; called by mutect2, pindel, varscan2
- LRRC4 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 62/551 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs776014596, COSV50813318; called by muse, mutect2, varscan2
- LRRC59 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV56813728; called by muse, mutect2, varscan2
- LVRN | c.2476G>T p.V826F | Missense Mutation (SNP) | VAF 78/355 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV63496096; called by muse, mutect2, varscan2
- MAGEB4 | c.842G>A p.S281N | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as COSV66775233; called by muse, mutect2
- MAP3K15 | c.855_857del p.I286del | In Frame Del (DEL) | VAF 11/84 reads (13%) | catalogued as rs780474404; called by pindel, varscan2
- MAP3K15 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as COSV58826225; called by muse, mutect2, varscan2
- MAP3K21 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1252604624, COSV64041037; called by muse, mutect2, varscan2
- MASP2 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs937409631, COSV68896121; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MCHR1 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs372132604; called by muse, mutect2, varscan2
- MCHR2 | c.511T>C p.Y171H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.658); catalogued as COSV55999859; called by mutect2, varscan2
- MED12L | c.5774T>C p.L1925P | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV56369256; called by muse, mutect2, varscan2
- MED13L | c.6619A>T p.M2207L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV56116097; called by muse, mutect2, varscan2
- MFN2 | c.2129T>C p.L710P | Missense Mutation (SNP) | VAF 112/270 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1557537223, CM062871, COSV52420625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MID2 | c.1574A>C p.E525A | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.67); catalogued as COSV53306974; called by muse, mutect2, varscan2
- MKRN1 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 75/221 reads (34%) | catalogued as COSV55435976; called by muse, varscan2
- MMP9 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs775382644, COSV64884234; called by muse, mutect2, varscan2
- MOAP1 | c.329del p.L110* | Frame Shift Del (DEL) | VAF 63/186 reads (34%) | catalogued as rs965671452; called by mutect2, pindel, varscan2
- MORC3 | c.609-1G>A p.X203_splice | Splice Site (SNP) | VAF 29/61 reads (48%) | catalogued as COSV68687772; called by muse, mutect2, varscan2
- MPZL1 | c.55T>C p.W19R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV63975409; called by muse, mutect2
- MROH5 | c.3907A>G p.S1303G | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV61471125; called by muse, mutect2, varscan2
- MRPS31 | c.1123T>C p.W375R | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60266141; called by muse, mutect2, varscan2
- MTF1 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65988377; called by muse, mutect2, varscan2
- MTTP | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.054); catalogued as COSV55503945; called by muse, mutect2, varscan2
- MUC16 | c.37887G>T p.R12629S | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.298); catalogued as COSV67446632, COSV67449425; called by muse, mutect2, varscan2
- MUC17 | c.1429G>A p.V477I | Missense Mutation (SNP) | VAF 116/245 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV60280795; called by muse, mutect2, varscan2
- MUC5B | c.6197G>A p.S2066N | Missense Mutation (SNP) | VAF 293/691 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1258297831, COSV71590173; called by muse, mutect2, varscan2
- NAA15 | c.1841del p.N614Mfs*22 | Frame Shift Del (DEL) | VAF 42/100 reads (42%) | catalogued as rs1283385686, COSV56718069; called by mutect2, varscan2
- NACA | c.53A>T p.Q18L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV63267738; called by muse, mutect2, varscan2
- NARF | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV59110593; called by muse, mutect2, varscan2
- NCAM2 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 71/135 reads (53%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.792); catalogued as COSV53057938; called by muse, mutect2, varscan2
- NCAPD3 | c.2150C>A p.P717H | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV73257892; called by muse, mutect2, varscan2
- NCKAP5L | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV60127655; called by muse, mutect2, varscan2
- NDN | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1217310499, COSV59358436; called by muse, mutect2, varscan2
- NDRG1 | c.1086C>A p.S362R | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.235); catalogued as COSV60482567; called by muse, mutect2, varscan2
- NDST1 | c.864G>A p.W288* | Nonsense Mutation (SNP) | VAF 38/103 reads (37%) | catalogued as COSV55785041; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 62/116 reads (53%) | catalogued as rs747914168; called by mutect2, varscan2
- NDUFV1 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs375322599; called by muse, mutect2, varscan2
- NEB | c.6695T>C p.M2232T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV50815085; called by muse, mutect2, varscan2
- NEK4 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 82/156 reads (53%) | catalogued as rs750596148, COSV51778864; called by muse, mutect2, varscan2
- NEO1 | c.2618C>T p.T873M | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs374229611; called by muse, mutect2, varscan2
- NEURL3 | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60440533; called by muse, mutect2, varscan2
- NEUROG1 | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV59081731; called by muse, mutect2, varscan2
- NGEF | c.1732A>G p.T578A | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV50914610; called by muse, mutect2, varscan2
- NGEF | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs757356334, COSV50914628; called by muse, mutect2, varscan2
- NGEF | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs781590948, COSV50914653; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 12/21 reads (57%) | catalogued as COSV53499514; called by mutect2, varscan2
- NLRP9 | c.534G>T p.R178S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1181785869, COSV60459882; called by muse, mutect2, varscan2
- NOA1 | c.814T>C p.C272R | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51736018; called by muse, mutect2, varscan2
- NPAP1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as rs764805101, COSV100275235, COSV61504673; called by muse, mutect2, varscan2
- NPEPL1 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61938171; called by muse, mutect2, varscan2
- NT5DC3 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67321249; called by muse, mutect2, varscan2
- NUCKS1 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV65652485; called by muse, mutect2, varscan2
- OBSCN | c.13247C>T p.A4416V | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs1245269048, COSV52743099; called by muse, mutect2, varscan2
- OBSCN | c.17908G>A p.E5970K | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs779884164, COSV52743127; called by muse, mutect2
- OBSCN | c.18781del p.A6261Hfs*101 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | catalogued as rs757515520; called by mutect2, pindel, varscan2
- OCA2 | c.2251G>A p.V751M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs780969715, COSV62339119; called by muse, mutect2, varscan2
- OMP | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs782075647, COSV53685717, COSV99581949; called by muse, mutect2, varscan2
- OPN4 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 55/270 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1247113380, COSV54114825; called by muse, mutect2, varscan2
- OR4N2 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 58/376 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs201108157, COSV60050074; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | catalogued as rs746200712; called by mutect2, varscan2
- OR6V1 | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV69236864; called by muse, mutect2, varscan2
- OR9G4 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 121/258 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.874); catalogued as rs142119383; called by muse, mutect2, varscan2
- OSBPL3 | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs939910153, COSV57652992; called by muse, mutect2
- OXTR | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57478473; called by muse, mutect2, varscan2
- PAK6 | c.2033C>T p.T678I | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs1256719444, COSV53044444; called by muse, mutect2, varscan2
- PAX2 | c.1060C>A p.P354T (on ENST00000428433 / NM_003987.5; = p.P331T on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/245 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.2); catalogued as COSV62290208; called by muse, mutect2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | catalogued as rs753190856; called by mutect2, varscan2
- PCDH10 | c.2530C>T p.R844W | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.65); catalogued as COSV52087916; called by muse, mutect2, varscan2
- PCDH15 | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 127/320 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs752356781, COSV57265804, COSV57366433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHGA4 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs1369885951, COSV53902918; called by muse, mutect2, varscan2
- PCDHGA9 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs749236674, COSV53902936; called by muse, mutect2, varscan2
- PCDHGB6 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 192/464 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.166); catalogued as COSV53902951; called by muse, mutect2, varscan2
- PCK2 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53748084; called by muse, mutect2, varscan2
- PDCD11 | c.4655C>A p.P1552H | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as COSV53294378; called by muse, mutect2
- PDE6C | c.1853C>T p.T618M | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as rs754752450, COSV65114803; called by muse, mutect2, varscan2
- PDZD4 | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1557078045, COSV51245394; called by muse, mutect2, varscan2
- PGM2L1 | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53345372; called by muse, mutect2, varscan2
- PHKA2 | c.865-2A>G p.X289_splice | Splice Site (SNP) | VAF 40/110 reads (36%) | catalogued as COSV66052588; called by muse, mutect2, varscan2
- PIGQ | c.1393C>A p.L465M | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.891); catalogued as COSV50312267; called by muse, mutect2, varscan2
- PJA1 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 102/231 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs756116062, COSV64052658; called by muse, mutect2, varscan2
- PKD1L1 | c.2615G>A p.G872D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.856); catalogued as rs1279098145, COSV56958473; called by muse, mutect2, varscan2
- PKD2L1 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100559490, COSV58394662; called by muse, mutect2, varscan2
- PKD2L2 | c.352C>A p.R118S | Missense Mutation (SNP) | VAF 128/270 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.403); catalogued as COSV51794849; called by muse, varscan2
- PKHD1L1 | c.6567del p.K2189Nfs*27 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | catalogued as rs769716668, COSV65737892; called by mutect2, pindel
- PLA2G12B | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs376569180; called by muse, mutect2, varscan2
- PLEKHG2 | c.3029A>G p.H1010R | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs768515583, COSV52678757; called by muse, mutect2, varscan2
- PLPPR4 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV64564460; called by muse, mutect2, varscan2
- PLXNA2 | c.3495G>T p.K1165N | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.984); catalogued as COSV65437824; called by muse, mutect2
- PLXNA4 | c.734T>G p.V245G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV58106577; called by muse, mutect2, varscan2
- PLXNB2 | c.419A>G p.E140G | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63780193; called by muse, varscan2
- PLXND1 | c.1466C>T p.T489M | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs771612189, COSV60709644; called by muse, mutect2
- PNKP | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs775168371, COSV55586436; called by muse, mutect2, varscan2
- POLD1 | c.2098G>A p.V700I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs868562435, COSV70954259; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLL | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54573680; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 27/79 reads (34%) | catalogued as rs745933237; called by mutect2, pindel, varscan2
- POLRMT | c.2911G>A p.A971T | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52112603; called by muse, mutect2, varscan2
- POM121 | c.1003G>T p.G335C (on ENST00000434423; = p.G70C on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/966 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs781924385, COSV57510895; called by muse, mutect2
- POMGNT1 | c.1425G>T p.W475C | Missense Mutation (SNP) | VAF 49/103 reads (48%) | PolyPhen probably damaging (1); catalogued as CM074442, COSV64339363; called by muse, mutect2, varscan2
- PPM1D | c.1535del p.N512Ifs*2 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs763475304; called by mutect2, pindel, varscan2
- PPM1H | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs747764925, COSV57370639; called by muse, mutect2, varscan2
- PPP1R8 | c.267C>G p.N89K | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV52579428; called by muse, mutect2
- PPP2R5C | c.1541G>T p.R514M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV58268448; called by muse, mutect2, varscan2
- PPP6R1 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1344090074, COSV69799295; called by muse, mutect2, varscan2
- PRCP | c.1196del p.G399Vfs*2 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | catalogued as COSV99074027; called by mutect2, pindel, varscan2
- PRDM16 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 89/204 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs371532027; called by muse, mutect2, varscan2
- PRMT5 | c.1199+1G>A p.X400_splice | Splice Site (SNP) | VAF 44/90 reads (49%) | catalogued as rs1390371612, COSV53544884; called by muse, mutect2, varscan2
- PRPF4B | c.2170C>G p.L724V | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.642); catalogued as COSV61783391; called by muse, mutect2, varscan2
- PRPF4B | c.2792A>T p.Y931F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as COSV61783400; called by muse, mutect2, varscan2
- PSME4 | c.4038+2T>C p.X1346_splice | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as COSV66363265; called by muse, mutect2
- PTEN | c.1107del p.S370Vfs*46 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as COSV64289196; called by mutect2, pindel, varscan2
- PTGER4 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56720106; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1489G>T p.G497W (on ENST00000421990 / NM_001136042.2; = p.G479W on NM_025267.3) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64181839; called by muse, mutect2
- PTGR1 | c.377+2T>C p.X126_splice | Splice Site (SNP) | VAF 12/50 reads (24%) | catalogued as COSV53027652; called by muse, mutect2, varscan2
- PTPN14 | c.2846G>A p.R949Q | Missense Mutation (SNP) | VAF 160/581 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65281643; called by muse, mutect2, varscan2
- PYGO2 | c.970C>A p.P324T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV63756629; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 30/62 reads (48%) | catalogued as rs755727862; called by mutect2, varscan2
- QPCT | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs761865842, COSV58119050; called by muse, mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | catalogued as rs754588466; called by mutect2, varscan2
- RAD21 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs765264685, COSV52056114, COSV52058512; called by muse, mutect2, varscan2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | catalogued as rs745353960; called by mutect2, pindel, varscan2
- RADIL | c.796T>C p.Y266H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV68199321; called by muse, mutect2, varscan2
- RAN | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 100/230 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54562126; called by muse, mutect2, varscan2
- RBM34 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 174/600 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV64012326; called by muse, mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 27/112 reads (24%) | catalogued as COSV56484832; called by mutect2, varscan2
- RDH8 | c.172A>G p.T58A (on ENST00000651512; = p.T38A on NM_015725.4) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50673946; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | catalogued as rs753959887; called by mutect2, varscan2
- RFX1 | c.2026G>A p.V676M | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs371857825; called by muse, mutect2, varscan2
- RFXANK | c.398C>G p.A133G | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV57393110; called by muse, mutect2, varscan2
- RNF168 | c.1516A>G p.K506E | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747676059, COSV58836781; called by muse, mutect2, varscan2
- ROGDI | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780893164, COSV58925668; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RP1L1 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66751975; called by muse, mutect2, varscan2
- RTN4 | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 44/130 reads (34%) | catalogued as rs761969807; called by mutect2, varscan2
- RTTN | c.5745G>A p.K1915= | Splice Region (SNP) | VAF 68/140 reads (49%) | catalogued as rs755262692, COSV99731296; called by mutect2, varscan2
- RYR1 | c.7750C>T p.H2584Y | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1330350845, COSV62089602; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SALL4 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.3); catalogued as rs1361178217, COSV53849968; called by muse, mutect2, varscan2
- SCAP | c.1571C>T p.T524I | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV55559043; called by muse, varscan2
- SDK2 | c.1058A>G p.K353R | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV66181681; called by muse, mutect2, varscan2
- SEC24D | c.2558G>A p.C853Y | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.911); catalogued as COSV54877044, COSV54880754; called by muse, mutect2, varscan2
- SFI1 | c.3650C>T p.A1217V (on ENST00000400288 / NM_001007467.3; = p.A1186V on NM_014775.4) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs1325349087, COSV56716129; called by muse, mutect2, varscan2
- SFRP2 | c.147del p.C50Afs*20 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as COSV56836838; called by mutect2, pindel, varscan2
- SFXN1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.553); catalogued as rs143516507; called by muse, mutect2, varscan2
- SH3GLB2 | c.998del p.P333Lfs*? (on ENST00000372559; = p.P333Lfs*111 on NM_020145.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as rs780247761; called by mutect2, pindel, varscan2
- SHFL | c.566del p.P189Rfs*67 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as COSV53462966; called by mutect2, varscan2
- SHOC2 | c.1692del p.P565Lfs*8 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | catalogued as rs1564732148; called by mutect2, pindel, varscan2
- SIGLEC6 | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV58432034; called by muse, mutect2, varscan2
- SLC16A5 | c.1472T>C p.V491A | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV55460388; called by muse, mutect2, varscan2
- SLC22A12 | c.1622G>A p.G541D | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV55447705; called by muse, mutect2, varscan2
- SLC24A4 | c.628T>C p.Y210H | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1054170620, COSV54107558; called by muse, mutect2, varscan2
- SLC25A24 | c.570del p.K190Nfs*29 | Frame Shift Del (DEL) | VAF 30/184 reads (16%) | catalogued as rs763273320; called by mutect2, varscan2
- SLC26A11 | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58338650; called by muse, mutect2, varscan2
- SLC26A9 | c.2119T>C p.Y707H | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV61600951; called by muse, mutect2
- SLC35A2 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs376547003, COSV54429268; ClinVar: benign; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 83/227 reads (37%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC43A2 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV56767722; called by muse, mutect2, varscan2
- SLC6A11 | c.1275G>A p.M425I | Missense Mutation (SNP) | VAF 115/278 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV54390034; called by muse, mutect2, varscan2
- SLITRK4 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 133/337 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV62022277; called by muse, mutect2, varscan2
- SLITRK6 | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV68389394, COSV68389672; called by muse, mutect2, varscan2
- SMARCD1 | c.1091T>C p.L364S | Missense Mutation (SNP) | VAF 107/232 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67411645; called by muse, mutect2, varscan2
- SMARCD2 | c.1385C>T p.T462I | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs959898303, COSV56737970; called by muse, mutect2
- SMC4 | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 108/234 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58445575; called by muse, mutect2, varscan2
- SMG7 | c.2545del p.M849* | Frame Shift Del (DEL) | VAF 16/107 reads (15%) | catalogued as rs749889899; called by mutect2, varscan2
- SOX13 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV65826235; called by muse, mutect2, varscan2
- SPEG | c.3918del p.R1307Gfs*12 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs771765677; called by mutect2, pindel, varscan2
- SPEM1 | c.144+2T>C p.X48_splice | Splice Site (SNP) | VAF 76/151 reads (50%) | catalogued as rs1180262425, COSV57209086; called by muse, mutect2, varscan2
- SSB | c.453+2T>C p.X151_splice | Splice Site (SNP) | VAF 20/204 reads (10%) | catalogued as COSV53625935; called by muse, mutect2
- STAC2 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 97/215 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV61064871; called by muse, mutect2, varscan2
- STK26 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53744733; called by muse, mutect2, varscan2
- STK38 | c.544G>C p.D182H | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57707560, COSV57707591; called by muse, mutect2
- STOML1 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs767304018, COSV57551018, COSV57551610; called by muse, mutect2, varscan2
- SUGP1 | c.1518T>A p.D506E | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55920388; called by muse, mutect2, varscan2
- SUPT5H | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1247172816, COSV63238486; called by muse, mutect2, varscan2
- SUV39H2 | c.752C>T p.S251L (on ENST00000354919 / NM_001193424.2; = p.S191L on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV57952595; called by muse, mutect2, varscan2
- SYCE2 | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV53365597; called by muse, mutect2, varscan2
- SYMPK | c.1102del p.E368Rfs*39 | Frame Shift Del (DEL) | VAF 23/56 reads (41%) | catalogued as rs1445349707, COSV99841573; called by mutect2, pindel, varscan2
- SYNGR3 | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV50191299; called by muse, mutect2, varscan2
- SYNPO | c.2613del p.G872Afs*10 (on ENST00000394243 / NM_001166208.2; = p.G628Afs*10 on NM_007286.6) | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as COSV56937879; called by mutect2, varscan2
- TACR1 | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202089843; called by muse, mutect2, varscan2
- TBC1D2 | c.1954T>C p.Y652H | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59782794; called by muse, mutect2
- TBCEL | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV52458675; called by muse, mutect2, varscan2
- TBX19 | c.550T>A p.C184S | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.619); catalogued as COSV63196778; called by muse, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TCF4 | c.1697G>T p.R566M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61890753; called by muse, varscan2
- TDRD6 | c.2750dup p.N917Kfs*15 | Frame Shift Ins (INS) | VAF 27/63 reads (43%) | catalogued as rs765467808; called by mutect2, varscan2
- TDRD6 | c.4558del p.M1520* | Frame Shift Del (DEL) | VAF 42/210 reads (20%) | catalogued as rs145334816, COSV60176047; called by mutect2, varscan2
- TET1 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751344073, COSV65382191; called by muse, mutect2, varscan2
- TFAP2C | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52370509; called by muse, mutect2
- TFDP2 | c.823C>T p.P275S (on ENST00000489671 / NM_001178139.2; = p.P215S on NM_006286.5) | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57705314; called by muse, mutect2
- TFR2 | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV50513894; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1668C>T p.V556= | Splice Region (SNP) | VAF 63/448 reads (14%) | catalogued as rs755103695, COSV51510115; called by muse, mutect2, varscan2
- TGM5 | c.845C>T p.A282V (on ENST00000220420 / NM_201631.4; = p.A200V on NM_004245.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55008670; called by muse, varscan2
- THBS4 | c.2828C>T p.T943I | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs933002305, COSV63467803; called by muse, mutect2, varscan2
- THOC6 | c.905G>A p.S302N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); catalogued as COSV50187214, COSV50187462; called by muse, mutect2, varscan2
- TLN2 | c.3640G>A p.A1214T | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV60885854; called by muse, mutect2
- TM2D3 | c.482G>A p.R161Q (on ENST00000333202 / NM_078474.3; = p.R135Q on NM_025141.3) | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.361); catalogued as rs749825529, COSV60880714; called by muse, mutect2, varscan2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 18/33 reads (55%) | catalogued as rs754390908; called by mutect2, varscan2
- TMCC2 | c.1361del p.P454Lfs*8 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | catalogued as COSV58001434; called by mutect2, pindel, varscan2
- TMEM131 | c.2971C>T p.R991C | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs377193013, COSV51770465; called by muse, mutect2, varscan2
- TMEM181 | c.944T>C p.L315S | Missense Mutation (SNP) | VAF 57/506 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.406); catalogued as COSV65562124; called by muse, mutect2, varscan2
- TMEM268 | c.277A>G p.R93G | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV55985605; called by muse, mutect2, varscan2
- TMEM87A | c.1184T>C p.I395T | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.081); catalogued as COSV67746305; called by muse, mutect2, varscan2
- TMOD2 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV51042787; called by muse, mutect2, varscan2
- TMPRSS6 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs777161515, COSV60975034; called by muse, mutect2, varscan2
- TMX3 | c.849-2A>G p.X283_splice | Splice Site (SNP) | VAF 21/159 reads (13%) | catalogued as COSV55184030; called by muse, mutect2, varscan2
- TNMD | c.642del p.I216Lfs*12 | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | catalogued as rs754014575; called by mutect2, varscan2
- TOX3 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as COSV54863026; called by muse, mutect2, varscan2
- TRIM36 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs749733979, COSV56688239; called by muse, mutect2, varscan2
- TRMT6 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 94/202 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766405213, COSV52542704; called by muse, mutect2, varscan2
- TRPM2 | c.4339G>A p.V1447I | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147625236; called by muse, mutect2, varscan2
- TRPM3 | c.4673G>T p.R1558M (on ENST00000357533 / NM_001366142.2; = p.R1413M on NM_020952.6) | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV62580326; called by muse, mutect2, varscan2
- TRPM5 | c.2165C>T p.T722I | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.063); catalogued as COSV50144843; called by muse, mutect2, varscan2
- TSPAN6 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV65957199; called by muse, mutect2, varscan2
- TSPOAP1 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV52104398; called by muse, mutect2
- TSSK2 | c.825del p.K276Sfs*30 | Frame Shift Del (DEL) | VAF 21/45 reads (47%) | catalogued as rs764514103; called by mutect2, pindel, varscan2
- TTI1 | c.459_460del p.A154Cfs*17 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as COSV65060570; called by mutect2, pindel, varscan2
- TTLL12 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as rs148865013; called by muse, mutect2, varscan2
- TTN | c.58435A>G p.N19479D (on ENST00000591111; = p.N12055D on NM_003319.4) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | PolyPhen benign (0.009); catalogued as COSV59899824; called by muse, mutect2, varscan2
- UBE2F | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs750109431, COSV56024857; called by muse, mutect2, varscan2
- UBE3D | c.317G>A p.C106Y | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.766); catalogued as COSV52751735; called by muse, mutect2
- UPK1B | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV51766213; called by muse, mutect2, varscan2
- USP19 | c.2890A>G p.R964G | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV60044997; called by muse, mutect2
- UTRN | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as rs778831647, COSV62328990, COSV62338121; called by muse, mutect2, varscan2
- VAT1L | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 79/205 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV56814772, COSV56829611; called by muse, mutect2, varscan2
- VIRMA | c.5302C>T p.R1768W | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776496785, COSV52582224; called by muse, mutect2, varscan2
- VPS11 | c.469C>T p.Q157* (on ENST00000620429; = p.Q701* on NM_021729.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as COSV56183962; called by muse, mutect2, varscan2
- VPS18 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs199697224, COSV55029016; called by muse, mutect2, varscan2
- VPS51 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV54206114; called by muse, mutect2, varscan2
- VPS54 | c.2264A>G p.Y755C | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55437850; called by muse, mutect2, varscan2
- VXN | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.385); catalogued as COSV59685250; called by muse, mutect2, varscan2
- WDFY1 | c.1064+2T>C p.X355_splice | Splice Site (SNP) | VAF 36/86 reads (42%) | catalogued as COSV51787885; called by muse, mutect2, varscan2
- WDR62 | c.3053G>A p.R1018Q | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs900306853, COSV54331832; called by muse, mutect2, varscan2
- WSB2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.602); catalogued as COSV57476908; called by muse, mutect2, varscan2
- XDH | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs756268720, COSV65147027; called by muse, mutect2, varscan2
- YIPF6 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1338859203, COSV65855353; called by muse, mutect2, varscan2
- YOD1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 130/357 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs1286433880, COSV60005913, COSV60006565; called by muse, mutect2, varscan2
- ZBTB41 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 109/330 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.129); catalogued as rs1204962451, COSV66358728; called by muse, mutect2, varscan2
- ZFYVE16 | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV62014293; called by muse, mutect2, varscan2
- ZFYVE16 | c.2687C>A p.S896Y | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV62014300; called by muse, mutect2, varscan2
- ZHX2 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs201110609, COSV58710435; called by muse, mutect2, varscan2
- ZMYND8 | c.1658G>A p.R553H (on ENST00000311275 / NM_001363741.2; = p.R573H on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as COSV53683204, COSV53696011; called by muse, varscan2
- ZNF236 | c.1678C>T p.H560Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53482761; called by muse, mutect2, varscan2
- ZNF431 | c.1534T>C p.Y512H | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as COSV60671597; called by muse, mutect2, varscan2
- ZNF440 | c.1108T>C p.C370R | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58370366; called by muse, mutect2, varscan2
- ZNF48 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs1314023518, COSV60782420; called by muse, mutect2, varscan2
- ZNF517 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs939913266, COSV63464515; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs781933025; called by mutect2, varscan2
- ZSCAN18 | c.221G>A p.C74Y | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53729864; called by muse, mutect2, varscan2
- AARS2 | c.2182del p.V728Cfs*33 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | called by mutect2, pindel, varscan2
- ABCA9 | c.143del p.F48Sfs*21 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel
- ADAMTS3 | c.2207dup p.G737Wfs*3 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- AIFM2 | c.191del p.K64Rfs*8 | Frame Shift Del (DEL) | VAF 31/88 reads (35%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.2949del p.K983Nfs*4 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | called by mutect2, varscan2
- ANKRD50 | c.2897dup p.L966Ffs*11 | Frame Shift Ins (INS) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- ANXA8L1 | c.608C>A p.T203N | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRPF3 | c.3099del p.K1034Nfs*18 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- BTBD7 | c.2303del p.P768Qfs*53 | Frame Shift Del (DEL) | VAF 22/97 reads (23%) | called by mutect2, pindel, varscan2
- CCDC148 | c.1278del p.K426Nfs*9 | Frame Shift Del (DEL) | VAF 85/199 reads (43%) | called by mutect2, pindel, varscan2
- CD6 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CDK12 | c.3627_3628del p.L1210Gfs*23 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by pindel, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- CP | c.858del p.F286Lfs*19 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 65/144 reads (45%) | called by mutect2, pindel, varscan2
- CREG2 | c.640del p.R214Dfs*5 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | called by mutect2, pindel, varscan2
- CYP3A5 | c.699del p.F233Lfs*4 | Frame Shift Del (DEL) | VAF 12/120 reads (10%) | called by mutect2, pindel
- DLEC1 | c.2521_2522del p.D841Lfs*10 | Frame Shift Del (DEL) | VAF 25/62 reads (40%) | called by mutect2, pindel, varscan2
- DNMT3B | c.561del p.Y188Tfs*4 | Frame Shift Del (DEL) | VAF 24/97 reads (25%) | called by mutect2, pindel, varscan2
- DNTTIP2 | c.1847del p.N616Tfs*33 | Frame Shift Del (DEL) | VAF 28/258 reads (11%) | called by mutect2, pindel
- DPP9 | c.2510dup p.N837Kfs*16 (on ENST00000598800; = p.N866Kfs*16 on NM_139159.5) | Frame Shift Ins (INS) | VAF 10/99 reads (10%) | called by mutect2, pindel, varscan2
- EMC8 | c.130del p.L44Wfs*34 | Frame Shift Del (DEL) | VAF 27/41 reads (66%) | called by mutect2, varscan2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | called by mutect2, pindel, varscan2
- ERVW-1 | c.353del p.G118Vfs*12 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- F13B | c.1146del p.K382Nfs*21 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- FBF1 | c.359del p.G120Vfs*31 (on ENST00000586717; = p.G134Vfs*31 on NM_001319193.1) | Frame Shift Del (DEL) | VAF 57/165 reads (35%) | called by mutect2, pindel, varscan2
- FGD6 | c.1240del p.M414Wfs*11 | Frame Shift Del (DEL) | VAF 81/324 reads (25%) | called by mutect2, pindel, varscan2
- FKBP3 | c.435del p.F145Lfs*18 | Frame Shift Del (DEL) | VAF 34/126 reads (27%) | called by mutect2, pindel, varscan2
- GAPVD1 | c.556dup p.S186Ffs*2 | Frame Shift Ins (INS) | VAF 17/86 reads (20%) | called by mutect2, pindel, varscan2
- GATB | c.300dup p.D101* | Frame Shift Ins (INS) | VAF 28/84 reads (33%) | called by mutect2, varscan2
- GDF5 | c.157del p.L53Wfs*34 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- GEMIN4 | c.2987_2989del p.E996del | In Frame Del (DEL) | VAF 27/59 reads (46%) | called by mutect2, pindel, varscan2
- GLI3 | c.45dup p.V16Sfs*2 | Frame Shift Ins (INS) | VAF 130/363 reads (36%) | called by pindel, varscan2
- GPR149 | c.1616dup p.R540Sfs*35 | Frame Shift Ins (INS) | VAF 44/112 reads (39%) | called by mutect2, pindel, varscan2
- HCFC2 | c.353del p.P118Lfs*43 | Frame Shift Del (DEL) | VAF 197/494 reads (40%) | called by mutect2, pindel, varscan2
- HCN1 | c.2065del p.Q689Sfs*91 | Frame Shift Del (DEL) | VAF 122/304 reads (40%) | called by mutect2, pindel, varscan2
- HDAC6 | c.3098del p.P1033Qfs*17 | Frame Shift Del (DEL) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- IGFBP2 | c.666del p.A223Pfs*54 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel
- IL4I1 | c.195dup p.G66Wfs*27 | Frame Shift Ins (INS) | VAF 40/119 reads (34%) | called by mutect2, pindel, varscan2
- IL7R | c.361del p.I121* | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- INHBB | c.575del p.G192Afs*57 | Frame Shift Del (DEL) | VAF 38/99 reads (38%) | called by mutect2, pindel, varscan2
- IRF3 | c.1148del p.G383Vfs*71 | Frame Shift Del (DEL) | VAF 143/423 reads (34%) | called by mutect2, pindel, varscan2
- ITIH2 | c.1278_1279+2dup | Frame Shift Ins (INS) | VAF 37/107 reads (35%) | called by mutect2, pindel, varscan2
- ITPKC | c.1830dup p.F611Lfs*49 | Frame Shift Ins (INS) | VAF 91/251 reads (36%) | called by mutect2, pindel, varscan2
- JAG1 | c.3359dup p.N1120Kfs*8 | Frame Shift Ins (INS) | VAF 97/230 reads (42%) | called by mutect2, pindel, varscan2
- KIF13B | c.959del p.G320Vfs*11 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- KMT2B | c.474_477dup p.P160Dfs*25 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | called by mutect2, pindel, varscan2
- LAMA3 | c.7738dup p.T2580Nfs*8 (on ENST00000313654 / NM_198129.4; = p.T971Nfs*8 on NM_000227.6) | Frame Shift Ins (INS) | VAF 22/68 reads (32%) | called by mutect2, varscan2
- LGI4 | c.578A>C p.H193P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.069); called by muse, mutect2
- LRP4 | c.175dup p.D59Gfs*5 | Frame Shift Ins (INS) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- LRRC66 | c.2555del p.L852Yfs*28 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, pindel, varscan2
- LSM1 | c.95del p.L32* | Frame Shift Del (DEL) | VAF 100/349 reads (29%) | called by mutect2, pindel, varscan2
- LTN1 | c.1239dup p.E414* | Frame Shift Ins (INS) | VAF 10/37 reads (27%) | called by mutect2, varscan2
- MAB21L3 | c.455del p.N152Mfs*15 | Frame Shift Del (DEL) | VAF 45/110 reads (41%) | called by mutect2, pindel, varscan2
- MAP1B | c.1919del p.K640Rfs*5 | Frame Shift Del (DEL) | VAF 20/134 reads (15%) | called by mutect2, pindel, varscan2
- MAP7D1 | c.107del p.P36Hfs*20 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- MDM1 | c.1771del p.T591Qfs*73 | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | called by mutect2, pindel, varscan2
- MRPS12 | c.120del p.K43Sfs*16 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, varscan2
- MTHFSD | c.946del p.D316Tfs*4 (on ENST00000360900 / NM_001159377.2; = p.D315Tfs*4 on NM_022764.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | called by mutect2, varscan2
- MVK | c.417del p.A141Rfs*18 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, pindel, varscan2
- NDOR1 | c.608del p.P203Rfs*8 | Frame Shift Del (DEL) | VAF 59/167 reads (35%) | called by mutect2, pindel, varscan2
- NEK9 | c.2016del p.F672Lfs*13 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | called by mutect2, pindel, varscan2
- NELFA | c.735del p.T246Qfs*20 (on ENST00000542778; = p.T235Qfs*20 on NM_005663.5) | Frame Shift Del (DEL) | VAF 20/85 reads (24%) | called by mutect2, pindel, varscan2
- NMI | c.350del p.N117Mfs*3 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- NOD1 | c.2520del p.S841Afs*2 | Frame Shift Del (DEL) | VAF 73/225 reads (32%) | called by mutect2, pindel, varscan2
- OR1Q1 | c.698del p.G233Afs*36 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- OR8G2P | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- PCDHGC3 | c.1452del p.D485Tfs*21 | Frame Shift Del (DEL) | VAF 23/141 reads (16%) | called by mutect2, pindel, varscan2
- PCGF3 | c.193del p.L65Cfs*26 | Frame Shift Del (DEL) | VAF 37/99 reads (37%) | called by mutect2, pindel, varscan2
- PDZD2 | c.4476del p.A1493Pfs*12 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- PHF14 | c.546del p.K182Nfs*19 | Frame Shift Del (DEL) | VAF 82/187 reads (44%) | called by mutect2, pindel, varscan2
- PRKCH | c.1842del p.F614Lfs*9 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- PSTPIP2 | c.213-3_247+9delinsAGCACCCTGAAGCGGGCCCTTGAAGTCTTCAAGCAGCGTAAGTGA p.X71_splice | Splice Site (DEL) | VAF 8/52 reads (15%) | called by pindel, varscan2*
- PTPRR | c.1313del p.N438Mfs*2 | Frame Shift Del (DEL) | VAF 30/155 reads (19%) | called by mutect2, pindel, varscan2
- SEC24C | c.2856_2860del p.L952Ffs*7 | Frame Shift Del (DEL) | VAF 135/305 reads (44%) | called by mutect2, pindel, varscan2
- SERTAD1 | c.291del p.S98Vfs*31 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | called by mutect2, pindel, varscan2
- SLC4A3 | c.366del p.T123Pfs*147 | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | called by mutect2, pindel, varscan2
- SPRY2 | c.923del p.P308Lfs*47 | Frame Shift Del (DEL) | VAF 54/144 reads (38%) | called by mutect2, pindel, varscan2
- SPSB1 | c.766del p.E256Rfs*53 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel, varscan2
- TAF7L | c.508del p.T170Pfs*35 | Frame Shift Del (DEL) | VAF 64/202 reads (32%) | called by mutect2, pindel, varscan2
- TBX4 | c.235_237del p.K79del | In Frame Del (DEL) | VAF 26/214 reads (12%) | called by pindel, varscan2
- THSD7A | c.3195del p.K1065Nfs*45 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by mutect2, pindel, varscan2
- TLE1 | c.1988dup p.Y665Vfs*26 | Frame Shift Ins (INS) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- TMEM196 | c.362_363del p.S121Ffs*11 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by pindel, varscan2
- TMEM236 | c.853dup p.Q285Pfs*21 | Frame Shift Ins (INS) | VAF 85/219 reads (39%) | called by mutect2, pindel, varscan2
- TNRC18 | c.5356del p.R1786Gfs*3 | Frame Shift Del (DEL) | VAF 29/82 reads (35%) | called by mutect2, pindel, varscan2
- TSKS | c.344del p.P115Lfs*19 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | called by mutect2, pindel, varscan2
- TSPYL2 | c.378del p.S127Afs*20 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2200A>G p.T734A | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- TUBGCP5 | c.2116C>T p.L706F | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBTF | c.1199del p.G400Afs*38 | Frame Shift Del (DEL) | VAF 50/118 reads (42%) | called by mutect2, pindel, varscan2
- UCP3 | c.136del p.E46Rfs*21 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel
- UNC5D | c.479del p.N160Tfs*16 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- WDR90 | c.4108del p.A1370Lfs*5 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 49/141 reads (35%) | called by mutect2, pindel, varscan2
- ZNF629 | c.2101del p.E701Kfs*9 | Frame Shift Del (DEL) | VAF 46/110 reads (42%) | called by mutect2, pindel, varscan2
- ABCC4 | c.1204C>T p.L402= | Silent (SNP) | VAF 77/147 reads (52%) | catalogued as COSV65309904; called by muse, mutect2, varscan2
- ABI3BP | c.2403G>A p.K801= | Silent (SNP) | VAF 72/180 reads (40%) | catalogued as COSV52528912; called by muse, mutect2, varscan2
- ABLIM2 | c.1815G>A p.K605= (on ENST00000341937 / NM_001130084.2; = p.K515= on NM_032432.5) | Silent (SNP) | VAF 59/123 reads (48%) | catalogued as COSV56400414; called by muse, mutect2, varscan2
- AC098582.1 | c.3090C>A p.T1030= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as COSV52017676; called by muse, mutect2, varscan2
- ACSM3 | c.1425A>G p.A475= | Silent (SNP) | VAF 60/240 reads (25%) | catalogued as COSV55500000; called by muse, mutect2, varscan2
- ADGRA1 | c.411C>T p.L137= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs1309435104, COSV66924822; called by muse, mutect2
- ADGRB1 | c.3210A>G p.G1070= | Silent (SNP) | VAF 84/226 reads (37%) | catalogued as COSV60092183; called by muse, mutect2, varscan2
- AFDN | c.342A>G p.Q114= | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as rs1382710139, COSV60038119; called by muse, mutect2, varscan2
- AKAP11 | c.4626G>A p.Q1542= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV50292835; called by muse, mutect2, varscan2
- AKR7A2 | c.358C>A p.R120= | Silent (SNP) | VAF 79/168 reads (47%) | catalogued as COSV52515657; called by muse, mutect2, varscan2
- ANGPT4 | c.22C>T p.L8= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV67920688; called by muse, mutect2, varscan2
- ANKRD11 | c.6312C>T p.D2104= | Silent (SNP) | VAF 4/7 reads (57%) | catalogued as rs777466601, COSV56355413; ClinVar: likely benign; called by muse, mutect2
- ANKRD39 | c.231C>T p.Y77= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs570413216, COSV66812854; called by muse, mutect2, varscan2
- ARHGEF1 | c.426G>A p.V142= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV61526377; called by muse, mutect2, varscan2
- ATP9A | c.1965G>A p.L655= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV58763413; called by muse, mutect2, varscan2
- ATXN3L | c.1014C>T p.V338= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs187826331, COSV66075246, COSV66076222; called by muse, mutect2, varscan2
- BAHCC1 | c.2661C>T p.P887= | Silent (SNP) | VAF 53/107 reads (50%) | catalogued as rs782449191, COSV57023085; called by muse, mutect2, varscan2
- BAHCC1 | c.7162C>T p.L2388= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs1555659513, COSV57023098; called by muse, mutect2, varscan2
- BATF2 | c.537G>A p.S179= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs768550449, COSV57249488; called by muse, mutect2
- BRF2 | c.210A>G p.Q70= | Silent (SNP) | VAF 102/818 reads (12%) | catalogued as COSV55102748; called by muse, mutect2, varscan2
- BSN | c.7989C>T p.S2663= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs921801511, COSV56513281; called by muse, mutect2, varscan2
- C10orf90 | c.951A>G p.E317= | Silent (SNP) | VAF 82/183 reads (45%) | catalogued as COSV52949814; called by muse, mutect2, varscan2
- C20orf96 | c.96G>A p.K32= (on ENST00000360321 / NM_153269.3; = p.K31= on NM_080571.1) | Silent (SNP) | VAF 27/190 reads (14%) | catalogued as COSV64403036; called by muse, mutect2, varscan2
- C5AR2 | c.696G>A p.R232= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV57255516; called by muse, mutect2, varscan2
- CACNA1E | c.6534C>T p.H2178= (on ENST00000367573 / NM_001205293.3; = p.H2135= on NM_000721.4) | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as rs778605231, COSV62383169; called by muse, mutect2, varscan2
- CAMSAP2 | c.3465T>C p.D1155= (on ENST00000236925 / NM_001297707.2; = p.D1144= on NM_203459.3) | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as COSV52667058; called by muse, mutect2
- CCDC198 | c.756C>A p.A252= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV53601352; called by muse, mutect2
- CCDC47 | c.942T>C p.D314= | Silent (SNP) | VAF 51/119 reads (43%) | catalogued as COSV56721832; called by muse, mutect2, varscan2
- CILK1 | c.1113G>A p.P371= | Silent (SNP) | VAF 87/197 reads (44%) | catalogued as rs768759468, COSV63153485; called by muse, mutect2, varscan2
- COL9A2 | c.1143G>A p.Q381= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as rs1173596156, COSV65622170; called by muse, mutect2, varscan2
- COLEC12 | c.1392C>A p.G464= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV68368761; called by muse, mutect2, varscan2
- CPAMD8 | c.2859A>G p.K953= (on ENST00000651564; = p.K906= on NM_015692.5) | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as rs760523143, COSV71595818; called by muse, mutect2, varscan2
- CRACDL | c.471C>T p.D157= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs751150288, COSV67406610; called by muse, mutect2, varscan2
- CTC1 | c.1233A>G p.S411= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV59852143; called by muse, mutect2
- CTPS2 | c.345T>G p.P115= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV63721384; called by muse, mutect2
- DCC | c.1683C>T p.Y561= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV100503250, COSV59085880; called by muse, mutect2, varscan2
- DIDO1 | c.1866G>T p.T622= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV56614246; called by muse, mutect2, varscan2
- DMPK | c.1086C>T p.T362= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs569670872, COSV52175625, COSV99353804; called by muse, mutect2, varscan2
- DOCK1 | c.3165C>T p.Y1055= | Silent (SNP) | VAF 114/283 reads (40%) | catalogued as rs200132165; called by muse, mutect2, varscan2
- DOCK5 | c.5505T>C p.T1835= | Silent (SNP) | VAF 43/190 reads (23%) | catalogued as rs1310284339, COSV52396354; called by muse, mutect2, varscan2
- DRAXIN | c.360C>T p.P120= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as rs369566278, COSV99610532; called by muse, mutect2, varscan2
- DSCAML1 | c.3138C>T p.P1046= (on ENST00000321322; = p.P986= on NM_020693.4) | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as rs199942618, COSV58382232; called by muse, mutect2, varscan2
- DUSP3 | c.438C>T p.D146= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as rs146645782; called by muse, mutect2, varscan2
- E4F1 | c.2121C>T p.A707= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs752283262, COSV57037677; called by muse, mutect2, varscan2
- EAF2 | c.564A>G p.S188= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV56543366; called by muse, mutect2, varscan2
- EEPD1 | c.1437C>T p.S479= | Silent (SNP) | VAF 57/201 reads (28%) | catalogued as rs759752037, COSV54196067; called by muse, mutect2, varscan2
- ENDOU | c.585C>T p.S195= (on ENST00000422538 / NM_001172439.2; = p.S154= on NM_006025.4) | Silent (SNP) | VAF 46/205 reads (22%) | catalogued as COSV57464573; called by muse, mutect2, varscan2
- ENTPD2 | c.828C>T p.L276= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs558487969, COSV57074668; called by muse, mutect2, varscan2
- EPX | c.321G>A p.Q107= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV56595041; called by muse, mutect2, varscan2
- FAM83G | c.2340G>A p.P780= | Silent (SNP) | VAF 56/139 reads (40%) | catalogued as rs1247112113, COSV58755440; called by muse, mutect2, varscan2
- FANCD2 | c.813G>A p.S271= | Silent (SNP) | VAF 77/185 reads (42%) | catalogued as rs773072936, CD072417, COSV55031830, COSV55032057; ClinVar: likely benign; called by muse, mutect2, varscan2
- GAB2 | c.327C>T p.V109= (on ENST00000361507 / NM_080491.3; = p.V71= on NM_012296.3) | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as COSV60866208; called by muse, mutect2, varscan2
- GABRA4 | c.336C>T p.G112= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs1296452467, COSV51922831; called by muse, mutect2, varscan2
- GJC2 | c.600G>A p.G200= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1463640924, COSV64512350; called by muse, mutect2, varscan2
- GNGT1 | c.195G>A p.K65= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs1477097163, COSV50352348; called by muse, mutect2, varscan2
- GPR26 | c.762C>T p.F254= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as rs144378636, COSV52932759; called by muse, mutect2, varscan2
- GPR65 | c.108G>C p.L36= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV50862358; called by muse, mutect2, varscan2
- GPX4 | c.426G>A p.P142= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as rs758523802, COSV62318727; called by muse, mutect2, varscan2
- HDAC5 | c.420G>A p.E140= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV56817337; called by muse, varscan2
- HDAC6 | c.2370C>T p.S790= | Silent (SNP) | VAF 77/183 reads (42%) | catalogued as rs782811110, COSV61927567; called by muse, mutect2, varscan2
- HEG1 | c.522C>T p.G174= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV60759573; called by muse, mutect2, varscan2
- HJV | c.435G>T p.P145= (on ENST00000336751 / NM_213653.4; = p.P32= on NM_145277.5) | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV60951196; called by muse, mutect2, varscan2
- HOXD9 | c.132C>T p.G44= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1426870162, COSV50890666; called by muse, mutect2
- IFT46 | c.765G>A p.R255= (on ENST00000264021 / NM_001168618.2; = p.R306= on NM_020153.3) | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV50593857; called by muse, mutect2, varscan2
- IGDCC3 | c.1407G>A p.E469= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV60076576; called by muse, mutect2, varscan2
- IL12RB2 | c.1140C>T p.H380= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1557435054, COSV52020502, COSV52027854; called by muse, mutect2, varscan2
- IL16 | c.243G>A p.S81= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs766454847, COSV57260528; called by muse, mutect2, varscan2
- IMPDH2 | c.1065G>T p.R355= | Silent (SNP) | VAF 66/158 reads (42%) | catalogued as COSV58244022; called by muse, mutect2, varscan2
- INSR | c.2763C>T p.Y921= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs1457244657, COSV57158021; called by muse, mutect2, varscan2
- ITIH2 | c.372C>T p.D124= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs749554375, COSV64432003; called by muse, mutect2, varscan2
- ITPR1 | c.7473C>T p.F2491= (on ENST00000354582; = p.F2436= on NM_002222.7) | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as COSV56969737; called by muse, mutect2, varscan2
- KCNJ3 | c.426C>A p.A142= | Silent (SNP) | VAF 60/139 reads (43%) | catalogued as COSV54531653, COSV54536301; called by muse, mutect2, varscan2
- KCNQ5 | c.390C>T p.H130= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV59650180; called by muse, mutect2, varscan2
- KDM5C | c.471C>T p.Y157= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as rs782147874, COSV62890780; called by muse, mutect2, varscan2
- KIF18B | c.1014G>A p.T338= | Silent (SNP) | VAF 25/193 reads (13%) | catalogued as rs753838998, COSV59270878; called by muse, mutect2, varscan2
- KIF6 | c.1224A>G p.S408= | Silent (SNP) | VAF 80/160 reads (50%) | catalogued as COSV54667838, COSV99760795; called by muse, mutect2, varscan2
- KLHL8 | c.846T>C p.C282= | Silent (SNP) | VAF 71/182 reads (39%) | catalogued as COSV56746918; called by muse, mutect2, varscan2
- KRTAP1-5 | c.468G>A p.P156= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs534171351, COSV62624057; called by muse, mutect2, varscan2
- LILRA2 | c.543C>T p.S181= | Silent (SNP) | VAF 98/401 reads (24%) | catalogued as rs551481305, COSV52188285; called by muse, mutect2, varscan2
- LOXL2 | c.693C>T p.C231= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as rs754957234, COSV66690413; called by muse, mutect2, varscan2
- MAGEA10 | c.165C>T p.S55= | Silent (SNP) | VAF 66/137 reads (48%) | catalogued as COSV54882951; called by muse, mutect2, varscan2
- MMP9 | c.477G>A p.V159= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV63433782; called by muse, mutect2, varscan2
- MNT | c.513G>A p.T171= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs1343178191, COSV51511141; called by muse, mutect2, varscan2
- MRC2 | c.3609G>A p.P1203= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs377027737; called by muse, mutect2, varscan2
- MRPL40 | c.333T>C p.T111= | Silent (SNP) | VAF 64/142 reads (45%) | catalogued as rs778510650, COSV54272279; called by muse, mutect2, varscan2
- MTAP | c.426G>A p.E142= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV101205471, COSV66476956; called by muse, mutect2, varscan2
- MTCL1 | c.4053C>T p.D1351= (on ENST00000306329 / NM_001378206.1; = p.D1032= on NM_015210.4) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1316107856, COSV60403479; called by muse, mutect2, varscan2
- MTMR14 | c.396A>G p.P132= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs774792546, COSV56003362; called by muse, mutect2, varscan2
- MUC2 | c.2349C>T p.F783= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs762811609; called by muse, mutect2, varscan2
- MYEOV | c.180C>T p.F60= | Silent (SNP) | VAF 49/156 reads (31%) | catalogued as COSV58293524; called by muse, mutect2, varscan2
- MYH3 | c.682C>T p.L228= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as COSV56861224; called by muse, mutect2, varscan2
- MYO1F | c.1407C>T p.H469= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs541294738, COSV57792067, COSV57801472; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO6 | c.2532C>T p.G844= | Silent (SNP) | VAF 54/137 reads (39%) | catalogued as COSV64117504; called by muse, mutect2, varscan2
- MYO9B | c.1533C>T p.V511= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as rs929451302, COSV68277134; called by muse, mutect2, varscan2
- MYRIP | c.207G>A p.S69= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs763254221, COSV56862514; called by muse, mutect2, varscan2
- NAA80 | c.462C>T p.R154= (on ENST00000417393 / NM_001200018.2; = p.R176= on NM_012191.4) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV56496846; called by muse, mutect2, varscan2
- NAAA | c.288C>T p.T96= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV54431257; called by muse, mutect2, varscan2
- NEMP1 | c.30G>A p.S10= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV55661662; called by mutect2, varscan2
- NEU2 | c.19C>T p.L7= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as COSV52091674; called by muse, mutect2, varscan2
- NFAT5 | c.2640G>A p.Q880= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV63025338; called by muse, mutect2, varscan2
- NFATC1 | c.1362G>A p.S454= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs758671503, COSV53695502; called by muse, mutect2, varscan2
- NOP16 | c.93G>A p.A31= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs1306244171, COSV51257414; called by muse, mutect2, varscan2
- NOX3 | c.1494C>T p.D498= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs745800906, COSV50148789, COSV99342899; called by muse, mutect2
- NTN5 | c.741T>G p.A247= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV54306541; called by muse, mutect2, varscan2
- NUP98 | c.411T>C p.S137= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as COSV61428976, COSV61440005; called by muse, mutect2, varscan2
- OGN | c.60A>G p.A20= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as rs1305230835, COSV52760324; called by muse, mutect2, varscan2
- ONECUT2 | c.984C>T p.G328= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV72203235; called by muse, mutect2, varscan2
- OR13F1 | c.496C>T p.L166= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV58250763; called by muse, mutect2, varscan2
- PAPPA2 | c.3123C>T p.H1041= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV62791214; called by muse, mutect2, varscan2
- PAX3 | c.1215G>A p.Q405= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV60586276; called by muse, mutect2, varscan2
- PCDHB6 | c.1335C>T p.N445= | Silent (SNP) | VAF 117/264 reads (44%) | catalogued as rs1554277740, COSV50689781; called by muse, mutect2, varscan2
- PCDHGA1 | c.2283G>A p.A761= | Silent (SNP) | VAF 20/356 reads (6%) | catalogued as COSV65295062; called by muse, mutect2
- PCGF3 | c.51C>T p.C17= | Silent (SNP) | VAF 52/106 reads (49%) | catalogued as rs376965583; called by muse, mutect2, varscan2
- PDE6B | c.2208G>T p.V736= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as COSV55324007; called by muse, mutect2
- PLA2G4A | c.102C>A p.A34= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV66551958; called by muse, mutect2, varscan2
- PLXNB2 | c.498C>T p.R166= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as rs200929294, COSV63780190; called by muse, varscan2
- PLXND1 | c.2112C>T p.R704= | Silent (SNP) | VAF 77/163 reads (47%) | catalogued as COSV60709631; called by muse, mutect2, varscan2
- PMP22 | c.342G>A p.A114= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs201871607, COSV56601311; ClinVar: likely benign; called by muse, mutect2, varscan2
- POTEA | c.303T>C p.T101= | Silent (SNP) | VAF 27/348 reads (8%) | called by muse, mutect2
- PPP2R2A | c.1167C>T p.R389= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV60095755; called by muse, mutect2
- PROC | c.468C>T p.G156= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs201105510, COSV52164845; called by muse, mutect2
- PRR22 | c.996C>T p.P332= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs144461430; called by muse, mutect2
- PTCHD3 | c.162C>T p.P54= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1313998326, COSV71256312; called by muse, mutect2, varscan2
- PTPRD | c.3744C>T p.D1248= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV61929736; called by muse, mutect2, varscan2
- RAVER1 | c.1083C>G p.L361= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV53343858; called by muse, mutect2, varscan2
- RELB | c.1173G>A p.E391= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as rs1338635714, COSV55508404; called by muse, mutect2, varscan2
- RER1 | c.135C>A p.V45= | Silent (SNP) | VAF 106/378 reads (28%) | catalogued as COSV60382907; called by muse, varscan2
- RNF20 | c.1101G>A p.L367= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV66660404; called by muse, mutect2, varscan2
- RRM1 | c.675T>C p.D225= | Silent (SNP) | VAF 143/340 reads (42%) | catalogued as COSV56163004; called by muse, varscan2
- RUSC1 | c.57C>T p.H19= | Silent (SNP) | VAF 76/293 reads (26%) | catalogued as rs1313946280, COSV52738262; called by muse, mutect2, varscan2
- SH3PXD2A | c.3228G>A p.V1076= (on ENST00000369774 / NM_001365079.1; = p.V1048= on NM_014631.2) | Silent (SNP) | VAF 67/176 reads (38%) | catalogued as COSV60115757; called by muse, mutect2, varscan2
- SHPRH | c.2286G>A p.L762= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs762813607, COSV51605020; called by muse, mutect2, varscan2
- SIL1 | c.1348C>T p.L450= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1375825013, COSV54528188; called by muse, mutect2, varscan2
- SLC18A3 | c.1470G>A p.P490= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV60320496; called by muse, mutect2, varscan2
- SLC37A1 | c.639C>T p.Y213= | Silent (SNP) | VAF 65/150 reads (43%) | catalogued as COSV100721763, COSV61401367; called by muse, mutect2, varscan2
- SLC7A5 | c.822G>A p.L274= | Silent (SNP) | VAF 70/187 reads (37%) | catalogued as COSV55363063; called by muse, mutect2, varscan2
- SMARCA2 | c.2337T>A p.I779= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV61804904; called by muse, mutect2
- SRCIN1 | c.1839C>T p.S613= (on ENST00000621492; = p.S579= on NM_025248.3) | Silent (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- SSBP3 | c.735A>G p.R245= (on ENST00000371320 / NM_145716.4; = p.R225= on NM_018070.5) | Silent (SNP) | VAF 81/170 reads (48%) | catalogued as COSV58884478; called by muse, mutect2, varscan2
- SUPT6H | c.2304C>T p.D768= | Silent (SNP) | VAF 64/149 reads (43%) | catalogued as rs530338458, COSV58924751; called by muse, mutect2, varscan2
- SYT14 | c.1326C>T p.F442= | Silent (SNP) | VAF 76/127 reads (60%) | catalogued as COSV55049488; called by muse, mutect2, varscan2
- TANC1 | c.5166G>A p.P1722= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs746679276, COSV55083458; called by muse, varscan2
- TANC2 | c.5412C>T p.S1804= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as COSV67330411; called by muse, mutect2, varscan2
- TAX1BP3 | c.351C>T p.A117= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs745885810, COSV50439773; called by muse, mutect2
- TCEAL9 | c.286C>A p.R96= | Silent (SNP) | VAF 80/187 reads (43%) | catalogued as COSV65488747; called by muse, mutect2, varscan2
- TCHH | c.5247C>T p.I1749= | Silent (SNP) | VAF 33/426 reads (8%) | catalogued as rs1358521236, COSV64273058; called by muse, mutect2
- TM9SF2 | c.978G>A p.L326= | Silent (SNP) | VAF 63/160 reads (39%) | catalogued as COSV64506218; called by muse, mutect2, varscan2
- TOM1L1 | c.1272G>A p.L424= | Silent (SNP) | VAF 57/116 reads (49%) | catalogued as COSV61946620; called by muse, mutect2, varscan2
- TUBG1 | c.618C>T p.D206= | Silent (SNP) | VAF 119/298 reads (40%) | catalogued as rs1200312178, COSV52220555; called by muse, mutect2, varscan2
- TYSND1 | c.1686G>A p.P562= | Silent (SNP) | VAF 63/132 reads (48%) | catalogued as rs780433703, COSV54642363; called by muse, mutect2
- UNK | c.1392C>T p.P464= | Silent (SNP) | VAF 99/223 reads (44%) | catalogued as rs376529764, COSV53145760; called by muse, mutect2, varscan2
- USP44 | c.381T>C p.D127= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as COSV51562119; called by muse, mutect2, varscan2
- USP54 | c.105T>C p.N35= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV60439846; called by muse, mutect2, varscan2
- VEGFB | c.216C>T p.C72= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as rs144214884; called by muse, mutect2, varscan2
- WASHC4 | c.1218C>T p.Y406= | Silent (SNP) | VAF 188/375 reads (50%) | catalogued as rs780588304, COSV59888568; called by muse, mutect2, varscan2
- YLPM1 | c.993A>G p.K331= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as COSV53106590; called by muse, mutect2, varscan2
- ZBTB16 | c.810C>T p.D270= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV60089412, COSV60100727; called by muse, mutect2, varscan2
- ZC3H14 | c.822T>C p.S274= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV51767243; called by muse, varscan2
- ZNF496 | c.159G>A p.A53= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as rs544463119, COSV54173724; called by muse, mutect2, varscan2
- ZNF512 | c.894G>A p.S298= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs570692052, COSV62673955; called by muse, mutect2, varscan2
- ZNF84 | c.1206C>G p.P402= | Silent (SNP) | VAF 54/129 reads (42%) | called by muse, mutect2, varscan2
- AIRE | c.880-200del | Intron (DEL) | VAF 36/119 reads (30%) | catalogued as rs757773290, COSV99381230; called by mutect2, pindel, varscan2
- CAPRIN1 | c.2065+16G>A | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as rs1327739871, COSV58218278; called by muse, mutect2, varscan2
- FBLN1 | c.1698-9534C>T | Intron (SNP) | VAF 45/157 reads (29%) | catalogued as rs755344602, COSV53044090; called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6048870 G>A | 3'Flank (SNP) | VAF 18/271 reads (7%) | catalogued as COSV51522680; called by muse, mutect2
- OBSCN | c.11659+4426T>C | Intron (SNP) | VAF 14/174 reads (8%) | catalogued as COSV99474003; called by muse, mutect2
- PRCP | c.168+15406T>C | Intron (SNP) | VAF 62/125 reads (50%) | catalogued as COSV57287571; called by muse, mutect2, varscan2
- TEX11 | c.-56del | 5'UTR (DEL) | VAF 82/182 reads (45%) | catalogued as rs772853520, COSV65467559; called by mutect2, varscan2
- TTN | c.10360+4036G>A | Intron (SNP) | VAF 6/64 reads (9%) | catalogued as COSV59899862; called by muse, mutect2
2 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 2 other) are not listed here.
